Gene-level copy-number profile of tumor specimen MP2PRT-PAUDSA-TMP1-A from MP2PRT case MP2PRT-PAUDSA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.0 years (1,450 days).
Specimen MP2PRT-PAUDSA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8952fbc4-2da5-4082-ba28-c3dc6337e6c6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUDSA-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/9a1a5d45-2e0c-4d8e-8232-244ccbddb1fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 313; copy number 1: 5,397; copy number 2: 52,709; copy number 3: 471.

Homozygous deletions (total copy number 0; autosomes only): 313 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,254,015, 41 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:90,114,838–90,367,699, 14 genes: IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr2:242,175,181–242,175,634, 1 gene: RPL23AP88.
- chr7:38,239,580–38,350,022, 18 genes (within-gene range 0–2): TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRGV5P, TRGV5.
- chr7:142,656,701–142,802,748, 26 genes: TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr9:37,002,697–37,008,040, 1 gene (within-gene range 0–2): AL161781.2.
- chr13:40,992,779–40,993,331, 1 gene (within-gene range 0–2): RGS17P1.
- chr14:22,438,547–22,507,723, 37 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34.
- chr14:105,672,308–106,791,233, 174 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
